Somatic mutation profile of tumor specimen C3N-02828-01 (aliquot CPT0215730006) from CPTAC case C3N-02828, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; Tumor grade: G2.
Specimen C3N-02828-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 660692a9-27b9-4621-aa7a-36f4a588dae6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02828-71 (Blood Derived Normal), aliquot CPT0215850002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c872b77-f6e8-4824-838c-fabdd5c0002b

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, Intron 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXO41 | c.82C>T p.H28Y | Missense Mutation (SNP) | VAF 50/215 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV104400957; called by muse, mutect2, varscan2
- KIF25 | c.131G>C p.G44A | Missense Mutation (SNP) | VAF 55/111 reads (50%) | SIFT tolerated (0.89); PolyPhen benign (0.017); catalogued as COSV63026658; called by muse, mutect2, varscan2
- PROZ | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 26/362 reads (7%) | catalogued as COSV61439113; called by muse, mutect2
- ARSK | c.1063G>T p.V355F | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ESYT2 | c.1725dup p.R576Sfs*6 (on ENST00000613624; = p.R500Sfs*6 on NM_020728.3) | Frame Shift Ins (INS) | VAF 35/150 reads (23%) | called by mutect2, pindel, varscan2
- FASTKD3 | c.1951C>A p.L651M | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2
- NDC80 | c.1678G>A p.V560I | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2
- PCDH15 | c.1448C>A p.A483E | Missense Mutation (SNP) | VAF 56/206 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRPA1 | c.538G>T p.A180S | Missense Mutation (SNP) | VAF 57/240 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- ACADSB | c.1161G>A p.E387= | Silent (SNP) | VAF 118/490 reads (24%) | called by muse, mutect2, varscan2
- DPYS | c.1089C>T p.G363= | Silent (SNP) | VAF 98/404 reads (24%) | catalogued as rs373819650; called by mutect2, varscan2
- NRXN2 | c.1215C>T p.D405= | Silent (SNP) | VAF 110/690 reads (16%) | catalogued as rs367937220, COSV99636335; called by muse, mutect2, varscan2
- SLC6A6 | c.230-874G>A | Intron (SNP) | VAF 69/225 reads (31%) | catalogued as rs895248774; called by muse, mutect2, varscan2
